Somatic mutation profile of tumor specimen MP2PRT-PAUJVM-TMP1-A (aliquot MP2PRT-PAUJVM-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUJVM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (942 days).
Specimen MP2PRT-PAUJVM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f66b72b4-4e66-4837-bbee-68c8ff12529b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJVM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJVM-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e94a96dd-7033-48bb-a50f-c4449b338cdb

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A2 | c.1922G>A p.R641K | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.506); catalogued as COSV66414988; called by muse, mutect2
- CPAMD8 | c.3218C>T p.T1073M (on ENST00000651564; = p.T1026M on NM_015692.5) | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746610790; called by muse, mutect2, varscan2
- DNAH7 | c.6877C>T p.R2293* | Nonsense Mutation (SNP) | VAF 19/228 reads (8%) | catalogued as rs757751406, COSV100414730; called by muse, mutect2
- GPR39 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 43/494 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.196); catalogued as rs1169254584; called by muse, mutect2
- KCNU1 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747155579, COSV67757404; called by muse, mutect2
- PKDREJ | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 54/397 reads (14%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); catalogued as COSV99478550; called by muse, mutect2, varscan2
- SLCO1C1 | c.450C>A p.S150R | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as COSV99859577; called by muse, mutect2
- CLCN6 | c.1539G>T p.L513F | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EYS | c.5699C>T p.A1900V | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- FGG | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 38/270 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MPP3 | c.1476G>T p.R492S | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- NR2F2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 33/540 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); called by muse, mutect2
- SNTG1 | c.778G>T p.A260S | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- UBC | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 51/396 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DOCK3 | c.5112T>C p.G1704= | Silent (SNP) | VAF 41/253 reads (16%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.690C>T p.T230= | Silent (SNP) | VAF 82/394 reads (21%) | catalogued as COSV64532093; called by muse, mutect2, varscan2
- ZNF469 | c.759C>T p.A253= | Silent (SNP) | VAF 74/335 reads (22%) | catalogued as rs975846019, COSV101458803; ClinVar: likely benign; called by muse, mutect2, varscan2
